Surgical pathology report (de-identified scan), TCGA case TCGA-EB-A44N, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Asterand, specimen TCGA-EB-A44N-01A (Primary Tumor).

Procurement Date: Laterality:

Path Report:SKIN TISSUE CHECKLIST

Specimen type: Excision of tumor

Tumor site: Skin, extremity

Tumor size: 1.7 x 1.6 x 0.5 cm

Tumor features: Ulcerated

Satellite nodules: Not specified

Histologic type: Nodular melanoma

Histologic grade:

Lymph nodes: Not specified

Lymphatic invasion: Not specified

Venous invasion: Not specified

Margins: Not specified

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: 5 mm deep, III Level by Clarc

ICD-O-3

melanoma, nodular

8721/3

Site: Skin, NOS

8-21-12
RD

C44.9

lw 8/14/12

Source: NCI Genomic Data Commons file b6780ace-7942-47dd-986a-8304117b2961 (TCGA-EB-A44N.506BDF80-398A-48F9-B1D4-FAF8FBB4BD1A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).